Gene-level copy-number profile of tumor specimen RC-B6SS-TTP1-A from RC case RC-B6SS, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Anaplastic large cell lymphoma, T cell and Null cell type; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 50.7 years (18,503 days).
Specimen RC-B6SS-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e8f762f1-ebc9-40ae-9af8-90fede64949f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6SS-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/08d804bf-7776-4b69-902c-ff6b7cfa1a27

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 1,634; copy number 2: 15,699; copy number 3: 19,373; copy number 4: 11,176; copy number 5: 3,933; copy number 6: 2,357; copy number 7: 1,702; copy number 8: 2,032; copy number 9: 452; copy number 10: 10.

Homozygous deletions (total copy number 0; autosomes only): 141 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:137,492,199–139,877,391, 42 genes: OLIG3, BTF3L4P3, AL356234.2, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1.
- chr7:38,256,337–38,296,233, 7 genes (within-gene range 0–3): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB.
- chr14:22,105,343–22,552,156, 92 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,196 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,433,492–37,947,057, 69 genes, copy number 7–9 (broad region; genes not listed).
- chr1:38,708,931–46,900,437, 284 genes, copy number 7–9 (broad region; genes not listed).
- chr1:64,470,129–66,374,579, 28 genes, copy number 7: CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P.
- chr1:100,083,563–101,787,572, 40 genes, copy number 7 (within-gene range 4–7): SASS6, AC093019.1, TRMT13, LRRC39, DBT, RPL23AP90, BRI3P1, AL445928.2, AL445928.1, RTCA-AS1, RTCA, MIR553, AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88, AC099670.1, LINC01349, AC099670.3, AC099670.2, VCAM1, EXTL2, AC104506.1, SLC30A7, HNRNPA1P68, DPH5, AC093157.2, AC093157.1, AC093157.3, AC119501.1, AL109741.1, S1PR1, AL109741.2, PPIAP7, LINC01307, LINC01709, RNU6-965P, RPSAP19.
- chr1:109,113,679–111,716,691, 102 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr1:143,419,625–146,061,948, 98 genes, copy number 7 (broad region; genes not listed).
- chr1:166,975,582–171,824,959, 119 genes, copy number 7 (broad region; genes not listed).
- chr1:179,025,804–186,190,949, 148 genes, copy number 7–8 (broad region; genes not listed).
- chr1:191,823,432–194,198,708, 31 genes, copy number 7: LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14.
- chr1:197,902,630–200,478,669, 35 genes, copy number 7–8 (within-gene range 6–8): C1orf53, LHX9, NEK7, PRR13P1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281.
- chr1:221,133,865–224,779,335, 70 genes, copy number 7 (broad region; genes not listed).
- chr1:234,261,706–234,274,465, 2 genes, copy number 9 (within-gene range 6–9): AL122008.1, SLC35F3-AS1.
- chr1:234,356,704–236,502,915, 66 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr1:240,775,514–244,709,033, 65 genes, copy number 7 (broad region; genes not listed).
- chr2:89,968,867–91,781,169, 39 genes, copy number 7: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr8:41,261,962–145,066,685, 1,574 genes, copy number 7–9 (broad region; genes not listed).
- chr10:134,465–7,411,486, 131 genes, copy number 7–8 (broad region; genes not listed).
- chr10:13,643,706–14,462,142, 1 gene, copy number 7 (within-gene range 6–7): FRMD4A.
- chr10:13,870,797–29,891,467, 251 genes, copy number 7 (broad region; genes not listed).
- chr10:33,177,492–33,336,262, 1 gene, copy number 7 (within-gene range 5–7): NRP1.
- chr10:33,288,304–33,917,804, 7 genes, copy number 7: RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629.
- chr11:109,864,295–110,296,712, 1 gene, copy number 7 (within-gene range 3–7): RDX.
- chr11:110,355,130–124,159,356, 370 genes, copy number 7–9 (broad region; genes not listed).
- chr12:12,310–2,812,902, 63 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr12:3,381,349–27,502,185, 601 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,503. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
